Somatic mutation profile of tumor specimen TCGA-25-2397-01A (aliquot TCGA-25-2397-01A-01D-0704-01) from TCGA case TCGA-25-2397, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 59.1 years (21,581 days).
Specimen TCGA-25-2397-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f3eb3c8-c191-42bb-bf0c-986a22be8c89.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-25-2397-10A (Blood Derived Normal), aliquot TCGA-25-2397-10A-01D-0704-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0da1efa2-2f20-401c-9585-3958691603a4

The open-access MAF lists 73 somatic variants for this specimen: 61 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 9, Frame Shift Del 5, Nonsense Mutation 4, RNA 3, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.745A>G p.R249G | Missense Mutation (SNP) | VAF 89/100 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs587782082, COSV52662247, COSV52676356, COSV52892337, COSV52908430; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS4 | c.1621C>T p.Q541* | Nonsense Mutation (SNP) | VAF 42/117 reads (36%) | catalogued as COSV100917846; called by muse, mutect2, varscan2
- ALKBH4 | c.721C>G p.L241V | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV99479500; called by muse, mutect2, varscan2
- ARL10 | c.719T>G p.L240W | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100119128; called by muse, mutect2, varscan2
- ASPM | c.9328C>G p.H3110D | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.171); catalogued as COSV54133282, COSV99660908; called by muse, mutect2, varscan2
- BCL2L14 | c.593C>G p.S198* | Nonsense Mutation (SNP) | VAF 165/307 reads (54%) | catalogued as COSV99845229; called by muse, mutect2, varscan2
- CCDC146 | c.2699A>G p.N900S | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.023); catalogued as rs372248491; called by muse, mutect2, varscan2
- CD36 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 101/253 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs756489185, COSV59214502, COSV59216834; called by muse, mutect2, varscan2
- CIT | c.2790T>A p.D930E | Missense Mutation (SNP) | VAF 45/55 reads (82%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.978); catalogued as COSV99950588; called by muse, mutect2, varscan2
- COL19A1 | c.3196G>C p.G1066R | Missense Mutation (SNP) | VAF 65/97 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100507139, COSV59564466; called by muse, mutect2, varscan2
- CTDP1 | c.1583C>A p.P528H | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT deleterious (0.04); PolyPhen benign (0.154); catalogued as rs532564462, COSV99310976; called by muse, mutect2, varscan2
- DNAJA1 | c.232G>C p.G78R | Missense Mutation (SNP) | VAF 71/218 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.224); catalogued as COSV100438598; called by muse, mutect2, varscan2
- DOCK10 | c.4871G>C p.G1624A | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV99291021; called by muse, mutect2, varscan2
- FAM90A1 | c.1115C>T p.T372I | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV100274464; called by muse, mutect2, varscan2
- FANCM | c.2593C>G p.Q865E | Missense Mutation (SNP) | VAF 54/169 reads (32%) | SIFT tolerated (0.64); PolyPhen benign (0.013); catalogued as rs776830147, COSV99951485; called by muse, mutect2, varscan2
- GRIK1 | c.437T>C p.F146S | Missense Mutation (SNP) | VAF 161/361 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as COSV100517591; called by muse, mutect2, varscan2
- HINFP | c.1405C>G p.Q469E | Missense Mutation (SNP) | VAF 60/151 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.04); catalogued as rs761842414, COSV100640876; called by muse, mutect2, varscan2
- IGSF10 | c.4114A>T p.T1372S | Missense Mutation (SNP) | VAF 141/334 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV99192204; called by muse, mutect2, varscan2
- KPRP | c.237G>T p.K79N | Missense Mutation (SNP) | VAF 133/299 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100908640; called by muse, mutect2, varscan2
- KY | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.089); catalogued as rs750351662, COSV71018091; called by mutect2, varscan2
- LARS2 | c.121T>A p.Y41N | Missense Mutation (SNP) | VAF 69/280 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV99648181; called by muse, mutect2, varscan2
- LCP2 | c.847C>G p.Q283E | Missense Mutation (SNP) | VAF 35/47 reads (74%) | SIFT tolerated (0.33); PolyPhen benign (0.07); catalogued as COSV50453940, COSV50454264; called by muse, mutect2, varscan2
- MASP1 | c.391T>A p.F131I | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99397559; called by muse, mutect2, varscan2
- MED10 | c.18C>A p.D6E | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (1); PolyPhen probably damaging (0.935); catalogued as COSV99740379; called by muse, mutect2, varscan2
- MIS18A | c.65A>T p.K22M | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.41); catalogued as COSV99267115; called by muse, mutect2, varscan2
- MPHOSPH10 | c.113A>T p.K38M | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); catalogued as COSV99731244; called by muse, mutect2, varscan2
- MRS2 | c.607A>C p.K203Q | Missense Mutation (SNP) | VAF 92/300 reads (31%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.517); catalogued as COSV99219085; called by muse, mutect2, varscan2
- MTCL1 | c.3293G>C p.C1098S (on ENST00000306329 / NM_001378206.1; = p.C779S on NM_015210.4) | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV100095361; called by muse, mutect2, varscan2
- MTHFR | c.254C>G p.A85G | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV100412138; called by muse, mutect2, varscan2
- MYO1D | c.2286G>A p.W762* | Nonsense Mutation (SNP) | VAF 87/103 reads (84%) | catalogued as rs745367684, COSV59016889; called by muse, mutect2, varscan2
- NECTIN1 | c.1033C>A p.H345N | Missense Mutation (SNP) | VAF 34/49 reads (69%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99872531; called by muse, mutect2, varscan2
- NME8 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200863038, COSV52246730, COSV99553828; called by muse, mutect2, varscan2
- OR8D4 | c.761C>T p.S254F | Missense Mutation (SNP) | VAF 103/377 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100361903; called by muse, varscan2
- OTOL1 | c.1047G>C p.L349F | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100020176; called by muse, mutect2, varscan2
- PAM | c.2398A>G p.T800A | Missense Mutation (SNP) | VAF 178/207 reads (86%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99173720; called by muse, mutect2, varscan2
- PHRF1 | c.1427C>T p.A476V (on ENST00000264555 / NM_001286581.2; = p.A475V on NM_020901.4) | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52758438, COSV99213201; called by muse, mutect2, varscan2
- PLXNB1 | c.851C>A p.S284Y | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.834); catalogued as COSV99603277; called by muse, varscan2
- PNPT1 | c.955G>C p.D319H | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as COSV99570368; called by muse, mutect2, varscan2
- RARB | c.431G>A p.R144Q (on ENST00000383772 / NM_001290216.2; = p.R137Q on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/230 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1387195672, COSV100412753, COSV58064588; ClinVar: uncertain significance; called by muse, mutect2
- RNF41 | c.829G>C p.A277P | Missense Mutation (SNP) | VAF 94/105 reads (90%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV100560310; called by muse, mutect2, varscan2
- RYR1 | c.11615A>T p.K3872M | Missense Mutation (SNP) | VAF 111/335 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100616637; called by muse, mutect2, varscan2
- SLC11A1 | c.487C>A p.L163I | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as COSV99262370; called by muse, mutect2, varscan2
- SLC25A25 | c.727T>A p.W243R | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100895365; called by muse, mutect2, varscan2
- STYXL2 | c.1714G>T p.A572S | Missense Mutation (SNP) | VAF 52/94 reads (55%) | SIFT tolerated (0.21); PolyPhen benign (0.039); catalogued as COSV99609701; called by muse, mutect2, varscan2
- TLE4 | c.1972G>A p.D658N | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs751862890, COSV54627568, COSV54629250; called by muse, varscan2
- TNIK | c.963T>G p.Y321* | Nonsense Mutation (SNP) | VAF 47/91 reads (52%) | catalogued as COSV99458966; called by muse, mutect2, varscan2
- TOX | c.1147C>G p.P383A | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); catalogued as COSV100789299; called by muse, mutect2, varscan2
- UBR1 | c.2794del p.A932Lfs*6 | Frame Shift Del (DEL) | VAF 70/187 reads (37%) | catalogued as COSV51930802; called by mutect2, pindel, varscan2
- USP21 | c.409G>C p.A137P | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.278); catalogued as rs1013474720, COSV99237696; called by muse, mutect2, varscan2
- VIM | c.847A>G p.N283D | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99813281; called by muse, mutect2, varscan2
- VSIG1 | c.1001C>G p.P334R | Missense Mutation (SNP) | VAF 86/158 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV99480435; called by muse, varscan2
- ZDHHC16 | c.1019G>C p.R340T | Missense Mutation (SNP) | VAF 126/136 reads (93%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as COSV100513051; called by muse, mutect2, varscan2
- ZNF667 | c.1261G>T p.G421W | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99410833; called by muse, mutect2, varscan2
- ZNF80 | c.467C>A p.T156N | Missense Mutation (SNP) | VAF 73/201 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV100352105; called by muse, mutect2, varscan2
- ZSWIM2 | c.1555C>T p.H519Y | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV99720422; called by muse, mutect2, varscan2
- GOLGA6A | c.1961_1962del p.Y654* | Frame Shift Del (DEL) | VAF 35/186 reads (19%) | called by mutect2, pindel, varscan2
- KDM3A | c.3581_3585del p.E1194Afs*14 | Frame Shift Del (DEL) | VAF 21/66 reads (32%) | called by mutect2, pindel, varscan2
- MATN4 | c.1132_1135+13del p.X378_splice (on ENST00000372754; = p.X337_splice on NM_003833.4) | Splice Site (DEL) | VAF 19/73 reads (26%) | called by mutect2, pindel, varscan2
- PPP1R32 | c.152_159del p.T51Kfs*45 | Frame Shift Del (DEL) | VAF 12/87 reads (14%) | called by mutect2, pindel*, varscan2*
- SLC7A6 | c.919-28_929del p.X307_splice | Splice Site (DEL) | VAF 82/260 reads (32%) | called by mutect2, pindel
- SYT3 | c.1181_1197del p.R394Pfs*16 | Frame Shift Del (DEL) | VAF 29/57 reads (51%) | called by mutect2, pindel, varscan2
- CTRC | c.618T>C p.D206= | Silent (SNP) | VAF 41/149 reads (28%) | catalogued as COSV101036440; called by muse, mutect2, varscan2
- DNAH9 | c.3523T>C p.L1175= | Silent (SNP) | VAF 102/258 reads (40%) | catalogued as COSV52386149; called by muse, mutect2, varscan2
- FOXD4L4 | c.288T>A p.S96= | Silent (SNP) | VAF 29/130 reads (22%) | called by muse, mutect2, varscan2
- GABRG2 | c.957C>A p.T319= (on ENST00000361925 / NM_001375343.1; = p.T279= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 97/498 reads (19%) | catalogued as COSV62716609; called by muse, mutect2, varscan2
- GRM4 | c.2244C>A p.I748= | Silent (SNP) | VAF 38/156 reads (24%) | catalogued as COSV100946065, COSV65217310; called by muse, mutect2, varscan2
- LRFN5 | c.1086T>A p.P362= | Silent (SNP) | VAF 62/250 reads (25%) | catalogued as COSV99985014; called by muse, mutect2, varscan2
- PFKFB3 | c.318C>T p.A106= | Silent (SNP) | VAF 24/514 reads (5%) | catalogued as rs1365280403, COSV100432268; called by muse, mutect2
- RESF1 | c.4857C>T p.T1619= | Silent (SNP) | VAF 45/87 reads (52%) | catalogued as rs760637892, COSV100440528; called by muse, mutect2, varscan2
- WSB1 | c.840A>C p.V280= | Silent (SNP) | VAF 105/178 reads (59%) | catalogued as COSV99286120; called by muse, mutect2, varscan2
- SSPOP | n.11771A>G | RNA (SNP) | VAF 121/134 reads (90%) | catalogued as rs1276668842, COSV100947873; called by muse, mutect2, varscan2
- SSPOP | n.12640T>G | RNA (SNP) | VAF 21/43 reads (49%) | catalogued as COSV100947875; called by muse, mutect2, varscan2
- UBTFL2 | n.739C>A | RNA (SNP) | VAF 70/160 reads (44%) | called by muse, mutect2, varscan2
